Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-A8PB, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-A8PB-01A (Primary Tumor).

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Antrum)

I) Parietal peritoneum.

- Uninvolved by neoplasia.

II) Stomach + omentum.

- Moderately differentiated papillary adenocarcinoma (intestinal type of Lauren) with extensive areas of necrosis measuring 11.0 x 4.0 x 2.65 cm localized in the antrum and pylorus.
- The tumor infiltrates the adjacent fat and the gastric serosa.
- Expansive tumoral edges.
- Angiolymphatic and perineural infiltration not detected.
- Adjacent gastric mucosae exhibiting atrophic gastritis with extensive intestinal metaplasia.
- Absence of neoplasia on the 37 lymph nodes examined of the lesser curvature (0/37) as well as on the 5 lymph nodes of the greater curvature (0/5).
- Omentum uninvolved by neoplasia.
- Surgical margins uninvolved by neoplasia.

III) Esophageal margin.

- Uninvolved by neoplasia.

IV) Celiac trunk.

- Lymph nodes uninvolved by neoplasia (0/4).

V) Gallbladder.

- Cholelithiasis.

VI) Lymph node of the anterior hepatic artery.

- Uninvolved by neoplasia (0/1).

Note: we didn't observe lymph nodes along with the greater curvature. We put all the material in alcohol and, if we find the lymph nodes, this result will be followed by a supplementary report.

ICD O.3
Adenocarcinoma, papillary NOS
8264/3
Site: Gastric antrum C16.3
JW 3/7/14

Criteria	11/1/13	Yes	No

Source: NCI Genomic Data Commons file f29eb604-3e7b-4d16-883a-567d28928798 (TCGA-VQ-A8PB.C190A606-2471-48BF-8558-B3F50B295224.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).